Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A3A2, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A3A2-01A (Primary Tumor).

Patient Key:

Surgical date:

TISSUE DESCRIPTION:

Portion liver (Segments V and VI - 790 grams, 15 x 13 x 8 cm) with attached gallbladder (12 x 4 x 3 cm). A1, A2, A3, A4, A5, A6, A7, A8, A9, A10, A11, A12

DIAGNOSIS:

Liver, segments V and VI, resection: Well differentiated hepatocellular neoplasm. In view of the size of the lesion, age of the patient, and a "nodule within a nodule" architectural pattern the lesion is best regarded as an encapsulated grade 1 hepatocellular carcinoma. Surgical margins are free of involvement. Liver nodule measures 12 x 11 x 7.5 cm. (Seen with Dr.

Gallbladder, cholecystectomy: Chronic cholecystitis with no stones; removed in the course of surgery.

PHOTOGRAPHED IN LAB

PRELIMINARY FROZEN SECTION CONSULTATION:

Hepatocellular adenoma vs grade 1 hepatocellular carcinoma.

1CD-0-3
Carcinoma, hepatocellular, NOS 8170/3
Site: liver C22.0 lw
9/22/11

Source: NCI Genomic Data Commons file 29753167-b45d-40a5-b3ff-d85c081324c1 (TCGA-DD-A3A2.91B547FA-DAB2-4B65-9AC4-5151D4524001.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).